Somatic mutation profile of tumor specimen TCGA-06-2561-01A (aliquot TCGA-06-2561-01A-02W-0837-08) from TCGA case TCGA-06-2561, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.4 years (19,505 days).
Specimen TCGA-06-2561-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52ed8b19-ffdf-4c7a-8baf-499e1eb6fcf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2561-10A (Blood Derived Normal), aliquot TCGA-06-2561-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/704eff30-2fa2-4e1d-a547-30558683e9b0

The open-access MAF lists 65 somatic variants for this specimen: 50 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 35, Silent 15, Frame Shift Del 6, Nonsense Mutation 5, Frame Shift Ins 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 51/339 reads (15%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 109/152 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY6 | c.1921C>T p.R641W | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754255254, COSV57168237; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440dup p.Q814Pfs*41 (on ENST00000289968 / NM_001006634.3; = p.Q736Pfs*41 on NM_018054.6) | Frame Shift Ins (INS) | VAF 18/134 reads (13%) | catalogued as rs773922861; called by mutect2, varscan2
- CCDC105 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV52963409; called by muse, mutect2, varscan2
- CDH24 | c.714dup p.L239Afs*67 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | catalogued as rs765496989; called by mutect2, varscan2
- CLIC5 | c.941C>G p.P314R (on ENST00000185206 / NM_001370649.1; = p.P155R on NM_016929.5) | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV51759661; called by muse, mutect2, varscan2
- CRACD | c.3202C>T p.Q1068* | Nonsense Mutation (SNP) | VAF 45/170 reads (26%) | catalogued as COSV51722431; called by muse, mutect2, varscan2
- DNAAF4 | c.8_9del p.L3Pfs*3 | Frame Shift Del (DEL) | VAF 27/98 reads (28%) | catalogued as COSV58249179; called by pindel, varscan2
- DNAH3 | c.1075T>C p.F359L | Missense Mutation (SNP) | VAF 174/608 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54525726; called by muse, mutect2, varscan2
- DUSP1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 43/928 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53319801; called by muse, mutect2
- EGFR | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs774146556, COSV51841003; called by muse, mutect2, varscan2
- FANCD2 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV55039109; called by muse, mutect2, varscan2
- GOLGA6A | c.1433T>G p.L478R | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV51806872; called by muse, mutect2, varscan2
- INTS6L | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV100878075, COSV66084580; called by muse, mutect2, varscan2
- LIPI | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 47/357 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.959); catalogued as COSV60712106; called by muse, mutect2, varscan2
- LTN1 | c.1829C>T p.S610L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs747264702; called by muse, varscan2
- MYO10 | c.3674dup p.S1226Lfs*25 | Frame Shift Ins (INS) | VAF 35/222 reads (16%) | catalogued as rs760302326, COSV57018963; called by mutect2, varscan2
- NMRK2 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs749330791, COSV51455539; called by muse, mutect2, varscan2
- OR1B1 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 220/365 reads (60%) | catalogued as rs556567774, COSV59171837; called by muse, mutect2, varscan2
- PIK3CG | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1370328855, COSV63246438, COSV63251375; called by muse, mutect2, varscan2
- PRKRA | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 32/576 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV57867544; called by muse, mutect2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 81/176 reads (46%) | catalogued as rs146650273; called by pindel, varscan2
- PUM1 | c.3304T>G p.C1102G | Missense Mutation (SNP) | VAF 90/248 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57086204; called by muse, mutect2, varscan2
- SAGE1 | c.2125T>A p.C709S | Missense Mutation (SNP) | VAF 69/351 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61014065; called by muse, mutect2, varscan2
- SLC5A8 | c.1567T>C p.Y523H | Missense Mutation (SNP) | VAF 29/977 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV73311134; called by muse, mutect2
- SPAG5 | c.2215C>G p.L739V | Missense Mutation (SNP) | VAF 202/758 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV58802057; called by muse, mutect2, varscan2
- SRGAP3 | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 54/265 reads (20%) | catalogued as COSV100841527, COSV64534037; called by muse, mutect2, varscan2
- TTN | c.10143C>A p.D3381E (on ENST00000591111; = p.D3335E on NM_003319.4) | Missense Mutation (SNP) | VAF 39/187 reads (21%) | PolyPhen benign (0.007); catalogued as COSV60300798; called by muse, mutect2, varscan2
- XRCC5 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV67536428; called by muse, mutect2, varscan2
- ZNF208 | c.2344T>G p.C782G | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV68111761; called by muse, mutect2, varscan2
- CREB1 | c.470_474del p.E157Gfs*20 (on ENST00000432329 / NM_134442.5; = p.E143Gfs*20 on NM_004379.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 90/311 reads (29%) | called by mutect2, pindel, varscan2
- DPEP3 | c.219del p.T74Pfs*14 | Frame Shift Del (DEL) | VAF 39/122 reads (32%) | called by mutect2, pindel, varscan2
- EFTUD2 | c.2644G>A p.G882S | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EIF1B | c.244del p.V82Lfs*22 | Frame Shift Del (DEL) | VAF 46/321 reads (14%) | called by mutect2, pindel, varscan2
- HNF1B | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 105/292 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIG3 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by mutect2, varscan2
- MAGEB4 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); called by muse, mutect2
- MAST1 | c.2348T>C p.F783S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- MLLT3 | c.335del p.P112Hfs*3 | Frame Shift Del (DEL) | VAF 253/582 reads (43%) | called by mutect2, pindel, varscan2
- NUDT21 | c.72C>G p.Y24* | Nonsense Mutation (SNP) | VAF 196/462 reads (42%) | called by muse, varscan2
- PDE6A | c.147C>G p.Y49* | Nonsense Mutation (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- PHAX | c.1071C>A p.D357E | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PHTF2 | c.1808C>T p.P603L (on ENST00000248550 / NM_001366089.1; = p.P565L on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/299 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PICALM | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.53); PolyPhen probably damaging (1); called by muse, mutect2
- SLC6A8 | c.1316T>C p.F439S | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.029); called by mutect2, varscan2
- STXBP5L | c.2911G>A p.V971I | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- THBS4 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 24/756 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- ZC3H7A | c.183C>A p.N61K | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF791 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); called by muse, mutect2
- ALG2 | c.363C>A p.I121= | Silent (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- ARHGAP35 | c.4365G>A p.V1455= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- EARS2 | c.1033C>T p.L345= | Silent (SNP) | VAF 209/326 reads (64%) | called by muse, varscan2
- ENTPD3 | c.87C>G p.V29= | Silent (SNP) | VAF 19/534 reads (4%) | called by muse, mutect2
- ERMN | c.201C>T p.N67= | Silent (SNP) | VAF 38/209 reads (18%) | called by muse, mutect2, varscan2
- KRT75 | c.987C>T p.D329= | Silent (SNP) | VAF 36/626 reads (6%) | catalogued as rs1408657186; called by muse, mutect2
- KRT82 | c.273C>T p.C91= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV57786597; called by muse, mutect2
- MRPS10 | c.312C>T p.I104= | Silent (SNP) | VAF 22/133 reads (17%) | called by mutect2, varscan2
- MTNR1B | c.897C>T p.F299= | Silent (SNP) | VAF 200/698 reads (29%) | catalogued as COSV57066766; called by muse, mutect2, varscan2
- MYO15A | c.9813C>A p.R3271= | Silent (SNP) | VAF 17/236 reads (7%) | called by muse, mutect2
- NUDT11 | c.177C>T p.G59= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV65664950; called by muse, mutect2, varscan2
- P4HB | c.465G>A p.V155= | Silent (SNP) | VAF 327/434 reads (75%) | called by muse, mutect2, varscan2
- PYGB | c.2235G>A p.Q745= | Silent (SNP) | VAF 10/53 reads (19%) | called by mutect2, varscan2
- SETDB1 | c.3522G>A p.G1174= | Silent (SNP) | VAF 185/1712 reads (11%) | called by muse, mutect2
- ZNF594 | c.1218T>C p.C406= | Silent (SNP) | VAF 14/474 reads (3%) | catalogued as rs1223227996; called by muse, mutect2
